Surgical pathology report (de-identified scan), TCGA case TCGA-HF-7134, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-7134-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details								Histology at
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date
[REDACTED]	TUMOUR	FF		GAST	[REDACTED]	[REDACTED]		0
	BUFFY	FF		GAST				6

[page 2 of 3]
nd staging								
Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiat ion	Pathologic al T	Pathologic al N	Clinical M
9	RESECT	Fundus of S:6		Adenocarcin II		T1b	N0	MP
15	RESECT	Fundus of S:6		Adenocarcin II		T1b	N0	MP

[page 3 of 3]
Histology **Slide URL**
Comments

Source: NCI Genomic Data Commons file ac19102d-c7b0-4375-90eb-c9a27cb1c59d (TCGA-HF-7134.1AE6EB34-BAC4-4983-A98A-7719A9E07159.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).